Surgical pathology report (de-identified scan), TCGA case TCGA-55-7903, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7903-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY:

PROCEDURE DATE: RECEIVED DATE: REPORT DATE: [REDACTED]

COPY TO:

Pre-Op Diagnosis
Lung mass
Post-Op Diagnosis
Same
Clinical History
Nothing indicated on requisition
Gross Description:

Container labeled [REDACTED] - right lower lobe of lung" is a 206 gram portion of recognizable pulmonary parenchyma grossly consistent with right lower lobe of lung. The specimen as received is 16.1 x 10.5 x 5.0 cm. The margin of resection is a previously sectioned bronchi with multiple staple lines. The pleura is wrinkled tan gray to brown and anthracotic streaked with a few nodular gray tan plaques up to 0.1 cm. Noted in the apparent lateral aspect in the central portion of the specimen there is a previously sectioned area of indurated umbilication measuring on reconstruction approximately 2.4 x 2.0 x 1.8 cm. This has been previously sectioned to reveal a lobulated gray tan to brown nodular lesion which grossly appears to extend to but not through the pleura in this area. This appears at its nearest point approximately 3.6 cm from the nearest bronchial margin. The remaining parenchyma is slightly diffusely consolidated mottled gray tan to pink with anthracotic streaking and focal areas of gross emphysematous change.

No other gross lesions are identified. Also received in the same container are three tissue cassettes each labeled [REDACTED]. Representative sections are submitted labeled as follows: A - shaved apparent bronchial margin, B through E - entire remaining lesion and surrounding tissue, F - representative pleura with nodular plaques, G - representative remaining parenchyma.

Container labeled [REDACTED] lymph node right lung" is a 2.0 x 2.0 x 1.0 cm portion of tan yellow fibroadipose tissue which has an embedded 1.1 cm gray brown fleshy nodule. The nodule

[REDACTED]

[page 2 of 4]
is bisected and entirely submitted in a single cassette.

Container labeled [REDACTED] lymph node right lung" is a 2.3 x 1.5 x 0.6 cm slightly friable nodular portion of focally shaggy fleshy gray brown to black tissue which on sectioning has a mottled gray black fleshy cut surface. The bisected nodule is entirely submitted in two cassettes.

Container labeled [REDACTED] lymph node right lung" are 2.9 x 2.0 x 1.3 cm aggregate of gray yellow to brown black fibrofatty tissue fragments with areas of fleshy gray black discoloration. The specimen is sectioned and entirely submitted in two cassettes.

Container labeled [REDACTED] lymph node right lung" are 1.2 x 0.9 x 0.4 cm fleshy gray black tissue fragments entirely submitted in a single cassette.

Container labeled [REDACTED] right lung middle lobe wedge" is a 17 gram roughly wedge-shaped portion of recognizable pulmonary parenchyma having an intact staple line at the margin of resection. The specimen overall is 14.4 x 2.5 x 1.5 cm. The pleura is focally shaggy mottled gray tan to brown with focal anthracotic streaking and areas of focal fragmentation. On sectioning the parenchyma is homogeneous and spongy with a slightly mottled tan brown cut surface. No gross lesions or cystic structures are identified. Representative sections are submitted in eight cassettes.

[REDACTED]

Microscopic Description:

The slides labeled [REDACTED] are examined. See diagnosis.

Final Diagnosis

Lung, right lower lobe of lung (lobectomy):

Tumor characteristics:

Specimen integrity: Intact.

Specimen laterality: Right.

Tumor site: Lower lobe.

Tumor size: 2.4 cm in greatest diameter.

Tumor focality: Unifocal.

Histologic type: Adenocarcinoma (see comment).

Histologic grade: Poorly differentiated.

Visceral pleural invasion: Not identified, carcinoma extends up to but not into pleura.

Tumor extension: Not identified.

Treatment effect: Not identified.

Lymphovascular space invasion: No unequivocal lymphovascular space invasion identified.

Surgical margin status:

Bronchial surgical margin: No carcinoma identified.

Pleural margin: No carcinoma identified.

Distance of tumor from closest margin: Less than 1 mm from the pleural margin.

Lymph node status:

One peribronchial lymph node demonstrating no metastatic carcinoma (0/1). PAS 9

Other:

Areas of subpleural fibrosis with interstitial fibrosis, interstitial chronic inflammation.

PAS 4,6

[REDACTED]

[page 3 of 4]
Emphysematous changes. PAS 4
Focal subpleural bone formation. PAS 4
pTN stage: pT1b N0
Level 9 lymph node, right lung (biopsy):
Reactive sinus histiocytosis and anthracosilicosis, no metastatic carcinoma identified within one lymph node (0/1). PAS 4
Level 7 lymph node, right lung (biopsy):
Reactive sinus histiocytosis and anthracosilicosis, no metastatic carcinoma identified within one lymph node (0/1). PAS 4
4R lymph node, right lung (biopsy):
Multiple fragments of lymph node demonstrating reactive sinus histiocytosis and anthracosilicosis, no metastatic carcinoma identified (see comment). PAS 4
Level 10 lymph node, right lung (biopsy):
Fragments of lymph node demonstrating reactive sinus histiocytosis and anthracosilicosis, no metastatic carcinoma identified (see comment). PAS 4
Right lung middle lobe (wedge biopsy):
Subpleural fibrosis and foci of interstitial fibrosis.
Scattered areas of interstitial chronic inflammation.
Emphysematous changes.
Intraalveolar macrophages.
No carcinoma identified. PAS 4,6 SPC-A

[REDACTED]

Comments

This is staged as a pT1b lesion based on the size of 2.4 cm in greatest diameter. The final stage should be performed in conjunction with the clinical information.

Sections of the tumor show a poorly differentiated large cell carcinoma. A panel of immunohistochemical stains is performed including CK5/6, p63, TTF1 and CK7 (with appropriate positive and negative controls). The neoplastic cells are positive for TTF1 and CK7. The neoplastic cells are negative for CK5/6 and p63. The overall histologic appearance in conjunction with the immunohistochemical stains is consistent with a poorly differentiated adenocarcinoma. In addition, some dense eosinophilic collagenous scar tissue is present suggesting this may have represented a so-called scar carcinoma. The carcinoma extends up to but not into the visceral pleura, being separated from the pleural margin by less than 1 mm. Clinical correlation and follow up is recommended.

At the request of the undersigned pathologist, these slides have been additionally reviewed by [REDACTED] who concurs with the diagnosis.

This test has been finalized at the [REDACTED]

This test was developed and its performance characteristics determined by [REDACTED] Laboratory. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified

[REDACTED]

[page 4 of 4]
under the Clinical Laboratory Improvement Amendments of [REDACTED]
[REDACTED] as qualified to perform high complexity clinical
laboratory testing.

<Sign Out Dr. Signature>

[REDACTED]

Source: NCI Genomic Data Commons file ba1753fe-b115-4e2f-82b7-dff4e3bc1b19 (TCGA-55-7903.F044AFA0-43C8-4047-A6BF-D46BFB42433C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).